Somatic mutation profile of tumor specimen TCGA-ZR-A9CJ-01B (aliquot TCGA-ZR-A9CJ-01B-11D-A387-09) from TCGA case TCGA-ZR-A9CJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.0 years (23,752 days).
Specimen TCGA-ZR-A9CJ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 122c5203-f787-4103-8e95-229f7b13b273.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZR-A9CJ-10A (Blood Derived Normal), aliquot TCGA-ZR-A9CJ-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90f877f5-a60e-4cf2-a57f-4940dc35cc5e

The open-access MAF lists 145 somatic variants for this specimen: 108 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 34, Nonsense Mutation 8, Frame Shift Del 6, RNA 2, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.94_96del p.K32del | In Frame Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs60872029; ClinVar: pathogenic; called by mutect2, pindel
- SACS | c.9305T>A p.L3102* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs886041949, COSV66537749; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.515T>A p.V172D | Missense Mutation (SNP) | VAF 23/38 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52683521, COSV52729554, COSV52811339, COSV52993405; called by muse, mutect2, varscan2
- ACOX1 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53132981; called by muse, mutect2, varscan2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2, varscan2
- AGBL1 | c.2720A>C p.K907T | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV66868237; called by muse, mutect2
- AOC1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189774343; called by muse, mutect2
- ARHGAP28 | c.1316A>C p.K439T (on ENST00000383472 / NM_001366230.1; = p.K280T on NM_001010000.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV51631890; called by muse, mutect2, varscan2
- C11orf42 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs199679205; called by muse, mutect2, varscan2
- CACNA1E | c.6484G>A p.V2162I (on ENST00000367573 / NM_001205293.3; = p.V2119I on NM_000721.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs373618053; called by muse, mutect2, varscan2
- CCDC171 | c.3730C>T p.R1244C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs200767961; called by muse, mutect2, varscan2
- CDC25B | c.950G>A p.R317Q (on ENST00000245960 / NM_021873.3; = p.R303Q on NM_004358.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as rs1240598537, COSV55659306; called by muse, mutect2, varscan2
- CELSR1 | c.5087G>A p.G1696D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773693439; called by muse, mutect2, varscan2
- CEP131 | c.2767G>A p.E923K (on ENST00000269392 / NM_001319228.2; = p.E920K on NM_014984.4) | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs577025986, COSV53950529; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- COL24A1 | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV65302069; called by muse, mutect2, varscan2
- EP300 | c.5038C>T p.R1680C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1254380600, COSV54337708; called by muse, varscan2
- EPAS1 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs375135104; ClinVar: uncertain significance; called by muse, mutect2
- EPB41L3 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1371649798; called by muse, mutect2, varscan2
- FAM135B | c.1902A>C p.K634N | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV52740215; called by muse, mutect2, varscan2
- FAM47A | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs45535434; called by muse, mutect2, varscan2
- FLG2 | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV66174223; called by muse, mutect2, varscan2
- GCN1 | c.5864A>C p.K1955T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56110525; called by muse, mutect2, varscan2
- HDGFL2 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1315362591; called by muse, mutect2, varscan2
- HEATR4 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs1323804503, COSV58569902; called by muse, mutect2, varscan2
- HECW1 | c.653A>T p.K218M | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67827716; called by muse, mutect2, varscan2
- HIRA | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs761210709, COSV54276348; called by mutect2, varscan2
- LAMA1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs139065838, COSV67541830; called by muse, mutect2, varscan2
- LRP2 | c.11542G>T p.E3848* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV55575153; called by muse, mutect2, varscan2
- MARCHF11 | c.726A>C p.K242N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV60126882, COSV60127659; called by muse, mutect2, varscan2
- MROH2B | c.4487A>C p.K1496T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV101270987; called by muse, mutect2, varscan2
- NME8 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52254619, COSV99553357, COSV99553951; called by muse, mutect2, varscan2
- OR51A4 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100985183; called by muse, mutect2, varscan2
- OR8I2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140511525; called by muse, mutect2, varscan2
- PRF1 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV100942709, COSV64615446; called by muse, mutect2, varscan2
- PRKG1 | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs1564449270; called by muse, mutect2, varscan2
- QRFPR | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs1279924172; called by muse, mutect2, varscan2
- ROS1 | c.4706G>A p.R1569Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141448347; called by mutect2, varscan2
- SLC44A5 | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63757821, COSV63770496; called by muse, mutect2
- SSH2 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99281506, COSV99283110; called by muse, mutect2, varscan2
- TEK | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV66235022; called by muse, mutect2, varscan2
- TLL1 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1292152415, COSV50263487, COSV50268157; called by muse, mutect2, varscan2
- TTK | c.1862C>A p.P621Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57883632; called by muse, mutect2, varscan2
- USH2A | c.8816C>T p.T2939I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs757734337; called by muse, mutect2, varscan2
- VCAM1 | c.927A>C p.Q309H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV54122084; called by muse, mutect2
- VPS9D1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66994575; called by muse, mutect2, varscan2
- ZNF345 | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV59322889; called by muse, mutect2, varscan2
- ACTG1 | c.128_132dup p.V45Sfs*23 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- ASAP3 | c.333_345del p.L112* | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- BARD1 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRAT1 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C3AR1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- CCDC191 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCNB3 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDH11 | c.1880T>A p.I627N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- COL24A1 | c.2497C>G p.P833A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CUL9 | c.7106_7109del p.T2369Rfs*70 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by pindel, varscan2
- DIDO1 | c.6347_6348del p.E2116Afs*140 | Frame Shift Del (DEL) | VAF 34/241 reads (14%) | called by pindel, varscan2
- FBXO41 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- FBXO42 | c.574T>C p.W192R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FCHSD2 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR61 | c.675_685del p.V226Qfs*143 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- HCAR2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- HCN1 | c.1677T>G p.C559W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUS1B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHA2 | c.377T>C p.L126S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA1 | c.4490_4494delinsT p.G1497Vfs*51 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by pindel, varscan2*
- MAMLD1 | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MED21 | c.146_151dup p.N49_P50dup | In Frame Ins (INS) | VAF 40/128 reads (31%) | called by mutect2, varscan2
- METAP1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MRM2 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MSMO1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MUC16 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MUC6 | c.6577_6580del p.S2193Hfs*48 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- MUC6 | c.2437C>T p.L813F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NFE2L2 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NFKB1 | c.118+1G>C p.X40_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- NGF | c.119T>G p.L40R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NPBWR1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NUP107 | c.798T>A p.S266R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- NUP188 | c.4355C>A p.T1452N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- NUP93 | c.2009T>G p.I670S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR52N5 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OR7D2 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- OVCH1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PCDH15 | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- PCDH9 | c.16T>A p.F6I | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PHYKPL | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PLTP | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- POSTN | c.1441A>T p.R481* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- SATB2 | c.1592A>C p.N531T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC27A6 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC5A8 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SPAG16 | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSX2 | c.496C>T p.H166Y (on ENST00000337502 / NM_175698.2; = p.P214= on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5 | c.3358G>C p.E1120Q (on ENST00000321680 / NM_001127715.2; = p.E1084Q on NM_139244.4) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, varscan2
- TAF3 | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCF12 | c.1601_1602insT p.S535Ifs*3 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, varscan2
- TEAD1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TPTE | c.1534A>G p.K512E (on ENST00000618007 / NM_199261.4; = p.K494E on NM_199259.4) | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- TTN | c.49292T>G p.L16431R (on ENST00000591111; = p.L9007R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTN | c.17296A>T p.I5766F (on ENST00000591111; = p.I4839F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen benign (0.341); called by muse, mutect2, varscan2
- UBE4B | c.2739G>T p.M913I (on ENST00000343090 / NM_001105562.3; = p.M784I on NM_006048.5) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- UCP2 | c.726C>A p.Y242* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- USP9X | c.4406C>T p.P1469L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- VPS13B | c.10279G>T p.A3427S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF800 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- ZSCAN1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC12 | c.1893G>A p.S631= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs150180336, COSV60915138; called by muse, mutect2, varscan2
- ADAMTS1 | c.1926G>A p.A642= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs371016638; called by muse, mutect2, varscan2
- ASIC5 | c.834C>T p.H278= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs771533226, COSV101611188; called by muse, mutect2, varscan2
- ATP8B4 | c.1173C>T p.S391= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs770476015, COSV52710285, COSV99464462; called by muse, mutect2, varscan2
- CD40LG | c.369G>A p.A123= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs148581967, COSV65698903; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEBPE | c.567G>A p.P189= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs373251741; called by muse, mutect2, varscan2
- CHRM3 | c.1509T>G p.T503= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- CHRNB2 | c.996G>A p.A332= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs762184252; called by muse, mutect2
- ELP1 | c.1647A>T p.S549= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs758761513; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT4 | c.5935T>C p.L1979= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- FBXO42 | c.573C>T p.G191= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- FHOD3 | c.3942G>A p.K1314= (on ENST00000359247 / NM_001281739.3; = p.K1331= on NM_025135.5) | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1471830922; called by muse, mutect2, varscan2
- GNGT1 | c.121A>C p.R41= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99949769; called by muse, mutect2, varscan2
- GPC6 | c.330A>G p.R110= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- H1-5 | c.63G>A p.K21= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs758785999; called by muse, mutect2, varscan2
- ISLR2 | c.1383C>T p.N461= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100679865; called by muse, mutect2, varscan2
- KLF16 | c.630C>T p.P210= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs760860819; called by muse, mutect2, varscan2
- LRTM2 | c.12G>T p.P4= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, varscan2
- MYO1C | c.1017C>T p.T339= (on ENST00000648651 / NM_001080779.2; = p.T304= on NM_033375.5) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs146685153; called by muse, mutect2, varscan2
- NXF3 | c.840G>A p.A280= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs919489808, COSV67702672, COSV67703068; called by muse, mutect2, varscan2
- OR1C1 | c.114C>A p.T38= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101376210; called by muse, mutect2, varscan2
- OR4S2 | c.759T>A p.T253= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- PLEKHM3 | c.1857G>T p.R619= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- PPP6R3 | c.427T>C p.L143= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- PROK1 | c.123C>T p.S41= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- PSD3 | c.678G>A p.Q226= | Silent (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.1110C>T p.A370= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as rs373766836; called by muse, mutect2, varscan2
- SLITRK1 | c.1317C>T p.S439= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs781770617; called by muse, mutect2, varscan2
- SPTA1 | c.5970C>T p.D1990= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- TRPA1 | c.1689C>T p.A563= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs771111843; called by muse, mutect2, varscan2
- UTP20 | c.5610G>A p.A1870= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs145450532; called by muse, mutect2, varscan2
- WASF3 | c.1236T>G p.S412= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs1291258048; called by muse, mutect2, varscan2
- ZNF664 | c.487A>C p.R163= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- ZNF823 | c.813C>T p.T271= (on ENST00000341191 / NM_001297610.2; = p.T227= on NM_017507.2) | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs373610199; called by muse, mutect2, varscan2
- MIR302F | n.50G>T | RNA (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- NBPF7 | n.1014G>C | RNA (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- ZBTB18 | c.-9G>A | 5'UTR (SNP) | VAF 17/85 reads (20%) | catalogued as rs1231058499, COSV62397000; called by muse, mutect2, varscan2
